CPTAC case C3L-02802 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2a971d49-1fcc-40eb-a02b-0736a0929f43

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1961; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 56.5 years (20,647 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G1; Residual disease: RX; Days to last known disease status: 844 days (2.3 years); Days to last follow up: 844 days (2.3 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.6 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 8; Margin status: Indeterminate.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 404, day 690, day 844.

Other clinical attributes
- Weight: 118.02 kg; Height: 170.18 cm; BMI: 40.75.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol history: Yes; Alcohol intensity: Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02802-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 200 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02802-22: Section location: Anterior and posterior endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-02802-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 26 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02802-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
